Gene-level copy-number profile of tumor specimen TARGET-10-PATEFF-09A from TARGET case TARGET-10-PATEFF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,366 days).
Specimen TARGET-10-PATEFF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.ca6ecc02-3019-5846-be61-476cb4f26930.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATEFF-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 359 have no estimate.
https://portal.gdc.cancer.gov/files/15d72a23-0e0d-41bc-8c0b-c1b1371134a7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 139; copy number 1: 156; copy number 2: 2,374; copy number 3: 5; copy number 4: 56,885; copy number 5: 580; copy number 6: 43; copy number 7: 1; copy number 8: 8; copy number 9: 73.

Homozygous deletions (total copy number 0; autosomes only): 139 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,318,861, 10 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr7:142,636,924–142,793,368, 26 genes: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr9:19,507,452–23,438,700, 78 genes (within-gene range 0–4) (broad region; genes not listed).
- chr14:22,415,362–22,490,553, 25 genes: AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 73 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 2 genes, copy number 9 (within-gene range 4–9): MALLP2, AC244205.1.
- chr2:88,857,161–90,005,629, 71 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 30. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
